Gene-level copy-number profile of tumor specimen TCGA-A6-6138-01A from TCGA case TCGA-A6-6138, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 61.7 years (22,523 days).
Specimen TCGA-A6-6138-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6dd2c2cd-8f15-4bbc-933a-6f7aa3cbe2ef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-6138-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13c6960a-b957-4e99-9df4-a76c701a1cda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,711; copy number 2: 42,086; copy number 3: 4,563; copy number 4: 2,456; copy number 5: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-6138-01A-11D-1770-01): tumor purity 0.62, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,636,060–29,681,155, 3 genes, copy number 5: SUMO2P1, MOG, ZFP57.

Autosomal genes at a single copy (total copy number 1): 8,331. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
